Somatic mutation profile of tumor specimen TCGA-HC-8259-01A (aliquot TCGA-HC-8259-01A-11D-2260-08) from TCGA case TCGA-HC-8259, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.1 years (18,309 days).
Specimen TCGA-HC-8259-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff22af38-9e16-4faf-bc48-808899f7a1f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8259-10A (Blood Derived Normal), aliquot TCGA-HC-8259-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b4e5e1b-1b3e-47ff-b8e1-48a459ff7e2e

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKAR | c.825T>G p.Y275* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV55615599; called by muse, mutect2
- ATP6V1E2 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV60576387; called by muse, mutect2
- BMP2K | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs1490113408, COSV55010922; called by muse, mutect2, varscan2
- C10orf90 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV52959560; called by muse, mutect2, varscan2
- CACNB2 | c.1091T>A p.L364H (on ENST00000324631 / NM_201596.3; = p.L309H on NM_000724.4) | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56637230; called by muse, mutect2
- CD163 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs201732077, COSV63135400; called by muse, mutect2, varscan2
- CHAF1A | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746983454, COSV56674778; called by muse, mutect2, varscan2
- DUSP8 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.105); catalogued as rs1268603074, COSV59030796; called by muse, mutect2, varscan2
- EEF1A2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV53205388; called by muse, mutect2
- ETNPPL | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56596769; called by muse, mutect2
- GOLGA3 | c.3842T>A p.V1281E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV52638058; called by muse, mutect2
- IRAK4 | c.386A>T p.D129V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV71210749; called by muse, mutect2
- IRS4 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.102); catalogued as COSV100929699, COSV64535062; called by muse, mutect2, varscan2
- NPAP1 | c.2458A>T p.I820F | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV61504408, COSV61509224; called by muse, mutect2, varscan2
- NWD1 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs772407281, COSV60342990; called by muse, mutect2, varscan2
- PLEKHA6 | c.1865C>A p.S622Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.259); catalogued as COSV55337145; called by muse, mutect2, varscan2
- PLXNA4 | c.4831T>A p.S1611T | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV58145943; called by muse, mutect2
- SOX14 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60163242; called by muse, mutect2
- SPHKAP | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs778910801, COSV60869051; called by muse, mutect2, varscan2
- TARS1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1240840651, COSV54310963; called by muse, mutect2
- TMTC2 | c.516C>G p.F172L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58277291; called by muse, mutect2, varscan2
- TTC17 | c.2066C>G p.P689R | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50013768; called by muse, mutect2, varscan2
- WDR70 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 26/337 reads (8%) | catalogued as COSV54278898; called by muse, mutect2
- XYLT1 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 16/222 reads (7%) | catalogued as COSV54491190; called by muse, mutect2
- ZC3HAV1 | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV54298779; called by mutect2, varscan2
- GGNBP2 | c.2060G>A p.C687Y | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- MTERF4 | c.246del p.T83Lfs*10 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- CCDC82 | c.330A>G p.E110= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV53594549; called by muse, mutect2
- GC | c.723A>G p.Q241= | Silent (SNP) | VAF 62/142 reads (44%) | catalogued as COSV56738588; called by muse, mutect2, varscan2
- HTR3A | c.516G>T p.S172= | Silent (SNP) | VAF 21/301 reads (7%) | catalogued as rs749670628, COSV55470670, COSV55470761; called by muse, mutect2
- KALRN | c.2373C>T p.D791= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1405217260, COSV53773669; called by muse, mutect2
- MPV17 | c.108G>A p.Q36= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV51991374; called by muse, mutect2
- SUSD5 | c.522C>T p.G174= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV58879216; called by muse, mutect2
- TTC8 | c.519A>G p.T173= (on ENST00000338104 / NM_001288781.1; = p.T183= on NM_144596.4) | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs1421706357, COSV57629019; called by muse, mutect2
